Somatic mutation profile of tumor specimen MMRF_1456_1_BM_CD138pos (aliquot MMRF_1456_1_BM_CD138pos_T1_KBS5U_L05770) from MMRF case MMRF_1456, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.8 years (21,848 days).
Specimen MMRF_1456_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c35fca04-70b0-4b88-a865-077ace504a60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1456_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1456_1_PB_Whole_C2_KBS5U_L05790; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd3a9cd0-81ca-4c2f-893f-9831f2d0fbd3

The open-access MAF lists 121 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 29, Intron 21, Silent 13, 3'Flank 6, 5'Flank 6, RNA 4, Nonsense Mutation 3, 5'UTR 2, Splice Site 2, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA2 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs200831475; called by muse, mutect2, varscan2
- AP5Z1 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs566001734, COSV62241071; called by muse, mutect2, varscan2
- BCL7A | c.92+2T>C p.X31_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as rs200458522; called by muse, mutect2, varscan2
- CDH23 | c.6343C>G p.R2115G | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs375329233, COSV56466235; called by muse, mutect2, varscan2
- CR1 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.977); catalogued as rs773894177; called by muse, mutect2, varscan2
- ENOSF1 | c.641-5T>C | Splice Region (SNP) | VAF 20/78 reads (26%) | catalogued as rs375389215; called by muse, varscan2
- HMCN1 | c.14551C>T p.R4851C | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs774426967, COSV54889970, COSV54913426; called by muse, mutect2, varscan2
- IGHV2-70 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370193821; called by muse, varscan2
- JAKMIP3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53821765; called by muse, mutect2, varscan2
- PPP4R1 | c.2731G>A p.E911K (on ENST00000400556 / NM_001042388.3; = p.E894K on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV53282176; called by muse, mutect2, varscan2
- RYR2 | c.11428C>T p.R3810* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as rs1446308525, COSV63689998; ClinVar: uncertain significance; called by mutect2, varscan2
- SLC22A3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs772653083, COSV51715974; called by muse, varscan2
- SLC5A10 | c.559+7T>A | Splice Region (SNP) | VAF 29/141 reads (21%) | catalogued as rs935755405; called by muse, mutect2, varscan2
- TBC1D16 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs772287340; called by muse, mutect2, varscan2
- TMBIM6 | c.418T>C p.Y140H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as COSV57278421; called by muse, mutect2, varscan2
- URB1 | c.2441C>T p.T814M | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs763908954; called by muse, mutect2, varscan2
- BAZ1A | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BCL11B | c.1150C>T p.R384C (on ENST00000357195 / NM_001282237.2; = p.R313C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2CD3 | c.1217+2T>G p.X406_splice | Splice Site (SNP) | VAF 47/132 reads (36%) | called by muse, mutect2, varscan2
- CACNB2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by muse, mutect2
- CDO1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CORO1A | c.44T>C p.F15S | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- DNAH6 | c.5642A>C p.D1881A | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ETS1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- FLT1 | c.1675T>G p.F559V | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- FSCN1 | c.734_751del p.A245_K250del | In Frame Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, varscan2
- GABRA1 | c.989A>C p.E330A | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H1-7 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGLV2-23 | c.220A>T p.K74* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, varscan2
- KIFC2 | c.2051A>C p.D684A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- KLHL32 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- LYN | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MRPL4 | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- NBEA | c.6631G>A p.E2211K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TBXAS1 | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- TMC1 | c.1912G>A p.G638S | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF302 | c.336C>A p.F112L (on ENST00000627982; = p.F111L on NM_018675.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC100868.1 | c.1521C>T p.H507= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- CORO1A | c.150C>T p.I50= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- DOCK5 | c.3603A>G p.L1201= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs765173430; called by muse, mutect2
- IGHV6-1 | c.33G>A p.V11= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs782442507; called by muse, mutect2, varscan2
- LECT2 | c.369A>T p.L123= | Silent (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- METTL24 | c.708T>C p.H236= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV58822153; called by muse, mutect2, varscan2
- PAPPA | c.3045G>A p.T1015= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs200371548; called by muse, mutect2, varscan2
- PRR35 | c.1299G>A p.P433= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs553664533; called by muse, mutect2, varscan2
- RNF17 | c.4428T>G p.P1476= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- SGO1 | c.72G>A p.E24= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- SORBS1 | c.3426A>G p.G1142= | Silent (SNP) | VAF 44/208 reads (21%) | called by muse, mutect2, varscan2
- TLR5 | c.1419C>A p.P473= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- TTN | c.69507G>A p.G23169= (on ENST00000591111; = p.G15745= on NM_003319.4) | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- ADGRB1 | c.*5G>A | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*1385A>C | 3'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- ATP10A | c.*290T>C | 3'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- ATP6V1G1 | c.*505G>T | 3'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020969 C>T | 5'Flank (SNP) | VAF 28/138 reads (20%) | catalogued as rs182306658, COSV55849224, COSV55851032; called by muse, mutect2, varscan2
- BCL7A | chr12:122021270 T>G | 5'Flank (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021411 G>A | 5'Flank (SNP) | VAF 18/87 reads (21%) | catalogued as COSV55846921, COSV55847077; called by muse, mutect2, varscan2
- BCL7A | chr12:122021532 G>A | 5'Flank (SNP) | VAF 13/62 reads (21%) | catalogued as rs180682804, COSV55846310; called by muse, mutect2, varscan2
- C1orf198 | c.*2578G>A | 3'UTR (SNP) | VAF 7/31 reads (23%) | catalogued as rs1255863684; called by muse, mutect2, varscan2
- CCDC169 | c.315+66T>C | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as rs1021384260; called by muse, mutect2
- CEBPA | c.*1129G>A | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- CRACD | c.*253A>C | 3'UTR (SNP) | VAF 24/80 reads (30%) | catalogued as rs1429945971; called by muse, mutect2, varscan2
- CTSG | c.203+57G>A | Intron (SNP) | VAF 22/101 reads (22%) | catalogued as rs375399974, COSV53537050; called by muse, mutect2, varscan2
- CYP21A2 | c.292+26T>A | Intron (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- DAB1 | c.-35G>A | 5'UTR (SNP) | VAF 29/165 reads (18%) | catalogued as rs75727843; called by muse, mutect2, varscan2
- DGKB | c.2307+459T>G | Intron (SNP) | VAF 39/108 reads (36%) | called by muse, mutect2, varscan2
- DLX6 | c.*921A>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- EEF1A1 | c.*995T>C | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- EMX2 | c.*621C>T | 3'UTR (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- EPHA8 | c.1315+18G>A | Intron (SNP) | VAF 19/88 reads (22%) | catalogued as rs199679973, COSV51273871; called by muse, mutect2, varscan2
- ERCC3 | c.*69A>C | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- FAM118A | c.*676G>C | 3'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- FAT1 | c.12369-11T>G | Intron (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- FOLH1B | n.1952C>T | RNA (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- FSHB | c.*1124G>T | 3'UTR (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1207-14437A>C | Intron (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+43524C>A | Intron (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- HNRNPH3 | c.251+88A>C | Intron (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1973C>T | Intron (SNP) | VAF 10/152 reads (7%) | catalogued as COSV55171661; called by muse, mutect2
- INPP4B | chr4:142025461 T>G | 3'Flank (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142026395 A>T | 3'Flank (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- INPP4B | chr4:142026958 T>C | 3'Flank (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142027079 A>G | 3'Flank (SNP) | VAF 14/78 reads (18%) | called by muse, varscan2
- INPP4B | chr4:142027175 A>C | 3'Flank (SNP) | VAF 11/90 reads (12%) | called by muse, varscan2
- ITGA1 | c.2772-82A>C | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- JADE2 | c.*2795T>C | 3'UTR (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- KCNE3 | c.*133G>T | 3'UTR (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*2812C>T | 3'UTR (SNP) | VAF 14/81 reads (17%) | catalogued as rs150473976; called by muse, mutect2, varscan2
- KLHL4 | c.*1454T>G | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- LAMC2 | c.3328+536G>A | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- LMO3 | c.*772dup | 3'UTR (INS) | VAF 15/67 reads (22%) | catalogued as rs1460137896; called by mutect2, varscan2
- LPP | c.*3845G>A | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- LTB | c.163-112G>A | Intron (SNP) | VAF 41/282 reads (15%) | catalogued as rs549758820; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851238 C>G | 5'Flank (SNP) | VAF 44/181 reads (24%) | catalogued as rs550463544; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851339 T>A | 5'Flank (SNP) | VAF 36/135 reads (27%) | catalogued as rs759776859; called by muse, mutect2, varscan2
- MYLK2 | c.*780C>T | 3'UTR (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- NAAA | c.498+374G>A | Intron (SNP) | VAF 14/98 reads (14%) | catalogued as rs972022020; called by muse, mutect2, varscan2
- NCAM2 | c.*32C>T | 3'UTR (SNP) | VAF 57/290 reads (20%) | catalogued as rs766737328, COSV99524861; called by muse, mutect2, varscan2
- NEGR1 | c.*2367A>G | 3'UTR (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- OR5H14 | chr3:98150516 A>C | 3'Flank (SNP) | VAF 29/110 reads (26%) | catalogued as rs1482747282; called by muse, mutect2
- OR5M4P | n.844C>T | RNA (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- PAIP2B | c.*1872G>A | 3'UTR (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- PIGL | c.526+123C>A | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- PLA2G4E | c.*1786dup | 3'UTR (INS) | VAF 17/105 reads (16%) | called by mutect2, pindel, varscan2
- PPP4R1L | n.2191T>G | RNA (SNP) | VAF 16/116 reads (14%) | catalogued as rs1329875888; called by muse, mutect2, varscan2
- RBCK1 | c.-324G>T | 5'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- RSPO3 | c.*166A>G | 3'UTR (SNP) | VAF 29/166 reads (17%) | called by muse, mutect2, varscan2
- S1PR3 | c.-148+509C>T | Intron (SNP) | VAF 27/152 reads (18%) | called by muse, varscan2
- SH3GL3 | c.45+43233C>T | Intron (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- SNX21 | c.*26T>A | 3'UTR (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- SNX30 | c.*4721G>T | 3'UTR (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- SUFU | c.*2183T>C | 3'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- TDG | c.408+80A>G | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- TECPR2 | c.*819G>A | 3'UTR (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- TFAP2A | c.539-47G>T | Intron (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- TFAP2A | c.539-48G>T | Intron (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- TMEM45A | c.*26G>C | 3'UTR (SNP) | VAF 34/230 reads (15%) | called by muse, varscan2
- TRBV25OR9-2 | n.28del | RNA (DEL) | VAF 31/201 reads (15%) | called by mutect2, pindel, varscan2
- VIPR1 | c.1011-19G>T | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as rs765948296, COSV57298587; called by muse, varscan2
- VMA21 | c.*2418G>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- ZMYND11 | c.*40dup | 3'UTR (INS) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
